Gene-level copy-number profile of tumor specimen ALCH-AE92-TTP1-A from ALCHEMIST case ALCH-AE92, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 78.5 years (28,673 days).
Specimen ALCH-AE92-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad7cdfdd-ff72-417d-9e4b-f7c3b7b1e4e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE92-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/e0df8f24-0794-43cd-8b34-878f50d7ca8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 4,882; copy number 2: 52,571; copy number 3: 1,380; copy number 4: 16; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,119,429–29,123,903, 1 gene (within-gene range 0–2): TMEM200B.
- chr2:127,625,997–127,681,786, 3 genes (within-gene range 0–2): AC010976.2, LIMS2, GPR17.
- chr2:240,868,824–240,896,889, 2 genes: AGXT, MAB21L4.
- chr3:48,636,463–48,669,174, 3 genes: CELSR3, MIR4793, LINC02585.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr5:659,862–693,352, 2 genes (within-gene range 0–2): TPPP, AC026740.1.
- chr8:141,353,403–141,432,454, 4 genes: AC100803.3, GPR20, AC100803.2, PTP4A3.
- chr8:141,434,545–141,437,954, 1 gene (within-gene range 0–1): AC100803.4.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr10:86,970,237–86,970,826, 1 gene (within-gene range 0–2): AL136982.7.
- chr15:85,750,336–85,756,237, 2 genes: AC021739.4, LINC02883.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–2): MIR1276, AC021739.1.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr16:88,468,918–88,469,031, 1 gene (within-gene range 0–1): MIR5189.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:321,392–322,453, 1 gene (within-gene range 0–1): AC129507.4.
- chr17:3,923,870–3,981,899, 2 genes: ATP2A3, LINC01975.
- chr17:17,810,399–17,837,011, 3 genes (within-gene range 0–2): SREBF1, MIR6777, MIR33B.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,264,252–149,264,816, 1 gene, copy number 6: AC245297.2.
- chr11:9,660,438–9,660,920, 1 gene, copy number 6: AC011979.1.

Autosomal genes at a single copy (total copy number 1): 2,040. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
